CGCI case HTMCP-01-06-00497 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/897c5a81-33ef-4ef1-857b-508ccf71f5b8

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 25 years; Vital status: Dead; Days to death: 253 days.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Liver; Classification of tumor: primary; Year of diagnosis: 2015; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 253 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Splenic lymph nodes; Sites of involvement: Liver.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Splenic; Tumor largest dimension diameter: 11 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CHOP-21; Days to treatment start: 15 days; Days to treatment end: 139 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 15 days; Days to treatment end: 139 days; Number of cycles: 6; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Pharmaceutical Therapy, NOS, for progressive disease; Pharmaceutical Therapy, NOS, for recurrent disease; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease; Surgery, NOS, for progressive disease.

Follow-up (4 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 70; ECOG performance status: 3.
- Days to follow up: 250 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Spleen; Days to recurrence: 250 days.
- Days to follow up: 250 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 250 days.
- Days to follow up: 253 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Negative; Specialized molecular test: Ki-67 > 90%.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 684 [Blood test normal range upper: 340].

Other clinical attributes
- Day 0: Weight: 52 kg; Height: 167 cm; BMI: 18.6.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-01-06-00497-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-06-00497-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-06-00497-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 1; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Primary pathology: Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Trucut Biopsy; Lymph nodes examined: No.
- Tests performed: LDH level: 684.
- Follow-up form: Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event 1: New tumor event type: Locoregional Recurrence; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form, New tumor event 2: New tumor event type: Distant Metastasis; New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharma adjuvant cycles count: 6; Treatment best response: Clinical Progressive Disease.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-06-00497-01A-01D-9392:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-06-00497-01A-01R-9392:
- % tumour top: 70
- % tumour bottom: 70
